TCGA case TCGA-2G-AAHJ — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bcd82852-bc21-453c-98a5-1da6254a5fa0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 51 years; Year of birth: 1943; Vital status: Alive.

Diagnoses (4)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 51.1 years (18,658 days); Year of diagnosis: 1994; Method of diagnosis: Orchiectomy; AJCC staging edition: 4th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 7,652 days (21.0 years); Ajcc serum tumor markers: S0; Sites of involvement: Rete Testis.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 18 days; Treatment dose: 30 Gy; Treatment outcome: Complete Response; Number of fractions: 15; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 1,875 days (5.1 years); Days to treatment end: 1,875 days (5.1 years); Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 7,190 days (19.7 years); Days to treatment end: 7,233 days (19.8 years); Treatment dose: 78 Gy; Number of fractions: 39; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
2. Subsequent primary of the testis (histology not recorded by GDC). Laterality: Bilateral; Age at diagnosis: 56.2 years (20,509 days); Days to diagnosis: 1,851 days (5.1 years).
3. Subsequent primary of the testis (histology not recorded by GDC). Age at diagnosis: 56.2 years (20,509 days); Days to diagnosis: 1,851 days (5.1 years); Prior treatment: Yes.
4. Subsequent primary of the prostate gland (histology not recorded by GDC). Age at diagnosis: 70.6 years (25,776 days); Days to diagnosis: 7,118 days (19.5 years); Prior treatment: Yes.

Follow-up (3 entries)
- Days to follow up: 7,233 days (19.8 years); Disease response: Tumor Free.
- Days to follow up: 7,652 days (21.0 years); Disease response: Tumor Free.
- Karnofsky performance status: 90; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -5: Lactate Dehydrogenase 281; Alpha Fetoprotein 5; Human Chorionic Gonadotropin 1.8.
- Day 8: Lactate Dehydrogenase 167; Alpha Fetoprotein 3.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by natural conception; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAHJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 140 mg.
  Slide TCGA-2G-AAHJ-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-2G-AAHJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAHJ-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Initial weight: 50 mg.
  Slide TCGA-2G-AAHJ-05A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-2G-AAHJ-05Z: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAHJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
